Gene-level copy-number profile of tumor specimen TCGA-FD-A43U-01A from TCGA case TCGA-FD-A43U, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 70.7 years (25,841 days).
Specimen TCGA-FD-A43U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.ff5bc7fd-9047-43db-97da-b0e9d6fc91db.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FD-A43U-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/90ed9c21-5083-4d6e-ba8c-007fb1ee86da

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 63; copy number 1: 15,213; copy number 2: 33,312; copy number 3: 10,920; copy number 4: 151; copy number 5: 149; copy number 7: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FD-A43U-01A-11D-A23T-01): tumor purity 0.2, ploidy 3.45, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 63 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,341,669–22,128,103, 63 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 161 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:58,796,237–60,455,214, 72 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr11:69,641,156–70,075,433, 12 genes, copy number 7 (within-gene range 4–7): CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584.
- chr16:27,787,528–29,370,272, 77 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 12,792. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
